Somatic mutation profile of tumor specimen TCGA-XU-A92T-01A (aliquot TCGA-XU-A92T-01A-11D-A423-09) from TCGA case TCGA-XU-A92T, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type AB, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 81.1 years (29,613 days).
Specimen TCGA-XU-A92T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ed96f70-f54b-4241-904a-cd837b1a84ce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XU-A92T-10A (Blood Derived Normal), aliquot TCGA-XU-A92T-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1c7e6d2-ab52-4be7-8ac4-653409b78756

The open-access MAF lists 27 somatic variants for this specimen: 24 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Nonsense Mutation 3, Silent 2, Intron 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 150/343 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- HRAS | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 15/32 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs104894226, CM053285, COSV54237021, COSV54237051; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AIFM1 | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1223488720, CM157340, COSV99780941; called by muse, mutect2, varscan2
- CUBN | c.3829+1G>A p.X1277_splice | Splice Site (SNP) | VAF 23/52 reads (44%) | catalogued as rs1349644537; called by muse, mutect2, varscan2
- DNAH8 | c.7582C>T p.P2528S | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100543380; called by muse, mutect2, varscan2
- ENAM | c.1042C>A p.P348T | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as rs942199747; called by muse, mutect2, varscan2
- FOXL2NB | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV57727512; called by muse, mutect2, varscan2
- GTSF1L | c.201C>G p.S67R | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV65932370; called by muse, mutect2, varscan2
- LIFR | c.235T>A p.Y79N | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.315); catalogued as rs763849976; called by muse, mutect2, varscan2
- MAP3K4 | c.4547G>A p.R1516H | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs773556218, COSV100815765; called by muse, mutect2, varscan2
- MYH14 | c.1779C>A p.D593E | Missense Mutation (SNP) | VAF 40/67 reads (60%) | SIFT tolerated (0.1); PolyPhen benign (0.155); catalogued as COSV51816759; called by muse, mutect2, varscan2
- MYO7B | c.4150C>T p.Q1384* | Nonsense Mutation (SNP) | VAF 17/38 reads (45%) | catalogued as COSV101267812; called by muse, mutect2, varscan2
- RTL5 | c.359C>G p.P120R | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.35); catalogued as COSV65454178; called by muse, mutect2, varscan2
- SCGB2B2 | c.192G>T p.Q64H | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.522); catalogued as rs749595919; called by muse, mutect2, varscan2
- TRO | c.3197A>G p.N1066S | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs764168100; called by muse, varscan2
- FGGY | c.53G>T p.G18V | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FN1 | c.1797C>A p.C599* | Nonsense Mutation (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
- HES3 | c.557A>G p.N186S | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LDLRAP1 | c.265A>T p.T89S | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- OVGP1 | c.289A>T p.I97F | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PPM1E | c.1720C>T p.Q574* | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
- PPP1R42 | c.284_285del p.K95Tfs*29 | Frame Shift Del (DEL) | VAF 35/115 reads (30%) | called by mutect2, pindel, varscan2
- RPRD2 | c.4369T>G p.F1457V | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.204); called by muse, mutect2
- SLMAP | c.643T>C p.S215P | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FKBPL | c.834G>A p.V278= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV100913598; called by muse, mutect2, varscan2
- KAT2A | c.1656C>A p.A552= | Silent (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- CENPF | c.7831-183A>G | Intron (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
